Surgical pathology report (de-identified scan), TCGA case TCGA-62-8398, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-62-8398-01A (Primary Tumor).

TSS Name: [REDACTED]

TSS Identifier: [REDACTED]

TSS Unique Patient #: [REDACTED]

Pathology Report-Summary:

Material:

lung, right, lower lobe: 17.0 x 15.0 x 9.0 cm with middle lobe: 12.0 x 9.0 x 4.0

tumor in lower lobe: 10.0 x 8.0 x 7.0 cm

Diagnosis:

Adenocarcinoma, mixed subtype (partially: acinar, papillary, BAC, solid)
Partially neuroendocrine

Infiltration of pleura visceralis

pT2, pN2 (10/35), pMx, G3

Supplementary examinations:

IHC:

Tumor cells positive for: CK7, CK18, CEA, partially positive for TTF1, NSE, Chromogranin A.

Tumor cells not positive for synaptophysin, CD56

Pathologist: [REDACTED]

Signature:

Date:

Source: NCI Genomic Data Commons file 7e799645-346f-4e7d-aa96-4deebc2a20eb (TCGA-62-8398.49359DCE-0DF1-4D52-87E8-ABA44FD43363.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).